Somatic mutation profile of tumor specimen TCGA-WY-A85D-01A (aliquot TCGA-WY-A85D-01A-11D-A36O-08) from TCGA case TCGA-WY-A85D, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 60.2 years (21,979 days).
Specimen TCGA-WY-A85D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bf7b35f-add0-48b2-8f30-cf2dbfe292a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WY-A85D-10A (Blood Derived Normal), aliquot TCGA-WY-A85D-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b0e5c24-ea0c-405e-a867-21e0a6f3ec4c

The open-access MAF lists 38 somatic variants for this specimen: 28 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 24, Silent 10, Nonsense Mutation 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 39/97 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 31/62 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781288, CM993216, COSV52664953, COSV52926626, COSV53155598; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANAPC1 | c.2089A>G p.R697G | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.056); catalogued as COSV100594896; called by muse, mutect2, varscan2
- AQP4 | c.905T>C p.I302T | Missense Mutation (SNP) | VAF 92/245 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as rs893806406, COSV101270536; called by muse, mutect2, varscan2
- ATRX | c.6391C>T p.R2131* | Nonsense Mutation (SNP) | VAF 86/101 reads (85%) | catalogued as COSV64873907, COSV64881210; called by muse, mutect2, varscan2
- B3GNT2 | c.606T>A p.S202R | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV100114237; called by muse, mutect2, varscan2
- DLK2 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.712); catalogued as rs765546362, COSV55089715; called by muse, mutect2, varscan2
- EIF4E | c.141T>G p.F47L | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as COSV99794855; called by muse, mutect2, varscan2
- FSTL5 | c.1465G>A p.V489I | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.782); catalogued as rs758993616, COSV100057803; called by muse, mutect2, varscan2
- GATA3 | c.1066A>G p.M356V | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV60517861; called by muse, mutect2, varscan2
- GLYAT | c.190-1G>T p.X64_splice | Splice Site (SNP) | VAF 13/69 reads (19%) | catalogued as COSV99557419; called by mutect2, varscan2
- KDF1 | c.1052A>G p.Q351R | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.55); catalogued as COSV100264564; called by muse, mutect2, varscan2
- LATS1 | c.804G>A p.W268* | Nonsense Mutation (SNP) | VAF 75/186 reads (40%) | catalogued as COSV53587011; called by muse, mutect2, varscan2
- LGI2 | c.1328C>G p.S443C | Missense Mutation (SNP) | VAF 117/287 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101180885; called by muse, mutect2, varscan2
- MEIS2 | c.769A>C p.N257H (on ENST00000561208 / NM_170675.5; = p.N244H on NM_002399.3) | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.887); catalogued as COSV99576739; called by muse, mutect2, varscan2
- OR4P4 | c.67G>A p.V23I | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1307030358, COSV100111779, COSV58921779; called by muse, mutect2, varscan2
- OR8K3 | c.912G>C p.W304C | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as COSV100449821, COSV57133310; called by muse, mutect2
- POLE | c.4284G>C p.E1428D | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100267337; called by muse, varscan2
- PRSS21 | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 92/244 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.398); catalogued as rs373819301; called by muse, mutect2, varscan2
- RIMKLA | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.601); catalogued as COSV101343481; called by muse, varscan2
- SPAG17 | c.881C>G p.T294S | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV100309640; called by muse, mutect2, varscan2
- SYCP2L | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV99305431; called by muse, mutect2, varscan2
- TRIM51 | c.1226T>C p.V409A | Missense Mutation (SNP) | VAF 50/129 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99792810; called by muse, mutect2, varscan2
- TTC37 | c.4481G>A p.R1494H | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.169); catalogued as rs369648889; called by muse, mutect2, varscan2
- USHBP1 | c.454A>G p.T152A | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.011); catalogued as COSV99394382; called by muse, mutect2, varscan2
- VPS13A | c.7229G>C p.G2410A | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100653083; called by muse, mutect2, varscan2
- IGKV1-16 | c.325T>C p.Y109H | Missense Mutation (SNP) | VAF 67/219 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- ZSWIM8 | c.3451dup p.T1151Nfs*5 (on ENST00000605216 / NM_001242487.2; = p.T1156Nfs*5 on NM_015037.3) | Frame Shift Ins (INS) | VAF 35/83 reads (42%) | called by mutect2, pindel, varscan2
- BCL11A | c.2148C>A p.V716= (on ENST00000335712 / NM_001365609.1; = p.V750= on NM_022893.4) | Silent (SNP) | VAF 92/235 reads (39%) | catalogued as COSV100185960; called by muse, mutect2, varscan2
- CDH16 | c.1845G>A p.G615= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV100233986; called by muse, mutect2, varscan2
- CNTNAP4 | c.342T>C p.S114= | Silent (SNP) | VAF 49/124 reads (40%) | catalogued as COSV100272223; called by muse, mutect2, varscan2
- FRS3 | c.201C>T p.Y67= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs143028177; called by muse, varscan2
- MUC5AC | c.16059G>A p.A5353= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs758626378, COSV100611505; called by muse, varscan2
- NLRP5 | c.1086C>T p.D362= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs779559885, COSV66766351; called by muse, mutect2, varscan2
- NOP53 | c.87G>T p.S29= | Silent (SNP) | VAF 47/119 reads (39%) | catalogued as rs763122158, COSV99622061; called by muse, mutect2, varscan2
- OR10R2 | c.897G>A p.T299= | Silent (SNP) | VAF 27/74 reads (36%) | catalogued as rs146808200; called by muse, mutect2, varscan2
- SCARF2 | c.1335C>T p.G445= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs978883346, COSV99839363; called by muse, mutect2
- SYNE2 | c.17967A>T p.A5989= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as COSV100648065; called by muse, mutect2, varscan2
